Surgical pathology report (de-identified scan), TCGA case TCGA-YL-A8HK, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site PROCURE Biobank, specimen TCGA-YL-A8HK-01A (Primary Tumor).

[page 1 of 2]
PROSTATE AND PELVIC/OBTURATOR LYMPH NODES; RADICAL PROSTATECTOMY:

HISTOLOGIC TYPE

ACINAR ADENOCARCINOMA

HISTOLOGIC GRADE (PRIMARY PATTERN+SECONDARY PATTERN = GLEASON SCORE):

4 + 5 = 9

TERTIARY PATTERN NOT PRESENT

PERCENTAGE OF DIFFERENT GLEASON PATTERNS

Not determined

TUMOR LOCATION

APEX

MID

BASE

BLADDER NECK

ANTERIOR

RIGHT

LEFT

LATERAL

RIGHT

LEFT

POSTERIOR

RIGHT

LEFT

EXTRA-PROSTATIC EXTENSION

PRESENT NON-FOCAL

SITE OF EXTRA-PROSTATIC EXTENSION

LATERAL

RIGHT

POSTERIOR

RIGHT

SEMINAL VESICAL INVASION

PRESENT

BOTH

SURGICAL MARGINS

INVOLVED BY INVASIVE CARCINOMA

BASE

POSTERIOR

RIGHT

LEFT

NATURE OF POSITIVE MARGINS

IN AREAS OF EXTRA-PROSTATIC EXTENSION

EXTENT OF POSITIVE MARGINS

MULTIFOCAL

MILLIMETRIC EXTENT OF POSITIVE MARGINS: not determined

GLEASON GRADE OF CARCINOMA PRESENT AT THE POSITIVE MARGINS

Not described

LYMPHOVASCULAR INVASION

PRESENT

PERINEURAL INVASION

PRESENT

TUMOR VOLUME/ SIZE OF LARGEST TUMOR NODULE

3.5X3.5X1.44=5.05CC

TREATMENT EFFECT ON CARCINOMA

NOT APPLICABLE

ICD-O-3
Adenocarcinoma, acinar 8140/3
Site Prostate C61.9
J011/29/13

[page 2 of 2]
LYMPH NODES

LEFT PELVIC

NUMBER OF NODES IDENTIFIED: 1

NUMBER OF NODES INVOLVED BY METASTASIS: __0

ADDITIONAL PATHOLOGIC FINDINGS

LN: Hyperplasia histiocitaria sinusal

OTHERS: IHC anti-cytokeratin negative

PATHOLOGICAL STAGING

pT3b

pN0

pMX

*COMMENT(S)

—

HIFAA Discrepancy		

Source: NCI Genomic Data Commons file 62fe232c-6cad-45d9-909c-72d3146cc959 (TCGA-YL-A8HK.AB7217AC-ABF7-4704-9413-9298DDE688EE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).